Gene-level copy-number profile of tumor specimen MP2PRT-PANVLH-TMP1-A from MP2PRT case MP2PRT-PANVLH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (720 days).
Specimen MP2PRT-PANVLH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4800420b-e29d-425a-8166-56cdb5ec2301.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PANVLH-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/ce1513c8-8969-4069-b4f8-d70eab96e5c6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 136; copy number 1: 3,363; copy number 2: 55,273; copy number 3: 115; copy number 4: 9.

Homozygous deletions (total copy number 0; autosomes only): 136 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,234,912, 40 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29.
- chr2:89,947,512–89,990,221, 5 genes: IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr7:38,239,580–38,340,998, 16 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes (within-gene range 0–2): TRGV5P, TRGV5, TRGV4.
- chr14:105,851,705–106,171,052, 59 genes (within-gene range 0–2): IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1, IGHV3-11, IGHVIII-11-1, IGHV1-12, IGHV3-13, IGHVIII-13-1, IGHV1-14, IGHV3-15, IGHVII-15-1, IGHV3-16, IGHVIII-16-1.
- chr14:106,263,362–106,301,862, 9 genes (within-gene range 0–1): IGHVII-22-1, IGHVIII-22-2, IGHV3-23, IGHV1-24, HOMER2P2, LINC00226, IGHV3-25, IGHVIII-25-1, IGHV2-26.
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.
- chr14:106,564,375–106,566,555, 2 genes (within-gene range 0–2): IGHVII-49-1, IGHV3-50.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 507. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
